Somatic mutation profile of tumor specimen MP2PRT-PAUPVZ-TMP1-A (aliquot MP2PRT-PAUPVZ-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUPVZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (982 days).
Specimen MP2PRT-PAUPVZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 818c8dd5-6e8a-4cb6-84b1-9f5271ae6a4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPVZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPVZ-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d7e9e3e-5a5b-459c-8a90-be0169a05fdc

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 40/301 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FER1L6 | c.4221G>T p.R1407S | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs10956162; called by muse, mutect2, varscan2
- FLT3 | c.1744A>C p.T582P | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV54048422; called by muse, mutect2
- FTHL17 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 62/706 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs774769349, COSV63266973; called by muse, mutect2
- GLI4 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 65/778 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs988007763; called by muse, mutect2
- MXRA5 | c.6352G>A p.G2118R | Missense Mutation (SNP) | VAF 83/560 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1049041476; called by muse, mutect2, varscan2
- OTOG | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs553254322; called by muse, mutect2, varscan2
- PLCE1 | c.5881C>T p.R1961* | Nonsense Mutation (SNP) | VAF 16/221 reads (7%) | catalogued as rs774196868, COSV53371264; called by muse, mutect2
- FUT11 | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 158/1217 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UGGT2 | c.1189T>A p.L397M | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- ADGRG3 | c.1527C>T p.F509= | Silent (SNP) | VAF 26/233 reads (11%) | catalogued as COSV59651886; called by muse, mutect2, varscan2
- MYMK | c.159C>T p.P53= | Silent (SNP) | VAF 44/340 reads (13%) | catalogued as rs754955056; called by muse, mutect2, varscan2
- NEURL4 | c.1635C>G p.A545= | Silent (SNP) | VAF 38/337 reads (11%) | called by muse, mutect2, varscan2
- PKD1L1 | c.1848C>T p.F616= | Silent (SNP) | VAF 41/308 reads (13%) | catalogued as rs747620748, COSV56961626; called by muse, mutect2, varscan2
